APOLLO case AP-ELSZ — Proteogenomic analysis of tumors from young women with breast cancer (APOLLO-BRCA-1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/e904c8ca-bb1c-4d27-be12-ae49c88efd01

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct and tubular carcinoma: ICD-O-3 morphology code: 8522/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS.

Biospecimens (2 samples)
- Sample AP-ELSZ-9R: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
- Sample AP-ELSZ-GN: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: OCT.
